Somatic mutation profile of tumor specimen ALCH-B28S-TTP1-A (aliquot ALCH-B28S-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B28S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 33.5 years (12,233 days).
Specimen ALCH-B28S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 907499d6-4af1-4476-96b3-c711cfc305ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28S-NB1-A (Blood Derived Normal), aliquot ALCH-B28S-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ee596a-1dd8-4ea0-b56e-364d270cf9d2

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM171A2 | c.2310G>A p.R770= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- KLHDC3 | c.399C>T p.A133= | Silent (SNP) | VAF 13/386 reads (3%) | called by muse, mutect2
